Surgical pathology report (de-identified scan), TCGA case TCGA-EL-A3H4, project TCGA-THCA (Thyroid Carcinoma), tissue source site MD Anderson, specimen TCGA-EL-A3H4-01A (Primary Tumor).

[page 1 of 4]
11/30/11

Surgical Pathology Report

Department of Pathology,
Tel:

DOB
Physician:

Sex: F

Collected:

Accession:

Received: Case type: Surgical Case

cc:

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

DIAGNOSIS

(A) CENTRAL COMPARTMENT INFERIOR ASPECT

Two lymph nodes, negative for tumor (0/2)

(B) RIGHT NECK LEVEL 2

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF SEVENTEEN LYMPH NODES (1/17)

Extracapsular extension absent.

(C) RIGHT NECK LEVEL 3

METASTATIC PAPILLARY THYROID CARCINOMA IN FOUR OF FIFTEEN LYMPH NODES (1/15)

Extracapsular extension absent.

(D) RIGHT NECK LEVEL 4

METASTATIC PAPILLARY THYROID CARCINOMA IN TWO OF SEVENTEEN LYMPH NODES (2/17)

Extracapsular extension absent.

(E) CENTRAL COMPARTMENT UPPER ASPECT

Three lymph nodes, negative for tumor (0/3)

(F) RADICAL THYROIDECTOMY RIGHT

PAPILLARY THYROID CARCINOMA CONVENTIONAL TYPE, WITH CYSTIC COMPONENT, 5.0 CM
THE TUMOR REPLACES THYROID LOBE AND INVADES INTO SURROUNDING SOFT TISSUE,
SKELETAL AND SMOOTH MUSCLE

(G) RETROPAROTID AND SCALENE NODES

METASTATIC PAPILLARY THYROID CARCINOMA IN FOUR OF SIX LYMPH NODES (4/6)

Extracapsular extension absent

(H) RIGHT PARATRACHEAL

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF FIVE LYMPH NODES (1/5)

Extracapsular extension absent

(I) SUPERIOR MEDIASTINAL

One lymph node and thymic tissue, negative for tumor (0/3)

(J) RIGHT ANTERIOR TRACHEAL WALL

Trachea, negative for tumor

(K) LEFT PARATRACHEAL

METASTATIC PAPILLARY THYROID CARCINOMA IN ONE OF THREE LYMPH NODES, 0.6 CM LARGEST
FOCUS (1/3)

Extracapsular extension absent.

(L) LEFT PARATRACHEAL MASS, RULE OUT PARATHYROID

Lymphoid tissue, no parathyroid tissue present, negative for tumor

GROSS DESCRIPTION

(A) CENTRAL COMPARTMENT INFERIOR ASPECT – Received is a 5.0 x 3.0 x 2.0 cm aggregate of fibroadipose tissue. The specimen is dissected to reveal three possible lymph nodes ranging from 0.3 up to 0.7 cm in greatest dimension. Representative sections are submitted.

SECTION CODE: A, three possible lymph nodes.

[page 2 of 4]
Surgical Pathology Report

Department of Pathology,

DOE
Physician

Sex: F

Collected:

Pathologist:

Accession

Received:

Case type: Surgical Case

cc

(B) RIGHT NECK LEVEL 2 – Received is a 3.0 x 2.0 x 1.5 cm portion of fibroadipose tissue. The specimen is dissected to reveal 18 possible lymph nodes ranging from 0.2 up to 1.5 cm in greatest dimension. The specimen is submitted entirely.

SECTION CODE: B1, five possible lymph nodes; B2, five possible lymph nodes; B3, four possible lymph nodes; B4, four possible lymph nodes.

(C) RIGHT NECK LEVEL 3 – Received is a 4.0 x 2.5 x 1.3 cm aggregate of fibroadipose tissue. The specimen is dissected to reveal 16 possible lymph nodes ranging from 0.2 up to 1.0 cm in greatest dimension. Representative sections are submitted.

SECTION CODE: C1, five possible lymph nodes; C2, five possible lymph nodes; C3, four possible lymph nodes; C4, two possible lymph nodes.

(D) RIGHT NECK LEVEL 4 – Received is a 4.0 x 2.5 x 1.2 cm aggregate of fibroadipose tissue. The specimen is dissected to reveal 17 possible lymph nodes ranging from 0.2 up to 0.8 cm in greatest dimension. The specimen is submitted entirely.

SECTION CODE: D1, five possible lymph nodes; D2, five possible lymph nodes; D3, four possible lymph nodes; D4, three possible lymph nodes.

(E) CENTRAL COMPARTMENT UPPER ASPECT – Received is a 5.0 x 4.0 x 2.0 cm portion of fibroadipose tissue. The specimen is dissected to reveal three possible lymph nodes ranging from 0.3 up to 0.7 cm in greatest dimension. Representative sections are submitted.

SECTION CODE: E, three possible lymph nodes.

(F) RADICAL THYROIDECTOMY (RIGHT) – Received is an unoriented irregular soft tissue specimen 8.0 x 5.0 x 4.0 cm, largely replaced by cystic and solid lesions. The cystic/pseudo cystic area measures 3.0 x 2.5 x 2.0 cm and solid component 5.0 x 4.5 x 4.0 cm respectively. The solid mass is firm, white to tan, with some papillary structures on cross section and grossly invades into surrounding soft tissue and muscle. Normal thyroid parenchyma is not appreciated grossly. The tumor grossly involves the softer tissue and muscles. Representative sections submitted in 15 cassettes.

SECTION CODE: F1-F4, cystic lesion; F5-F15, solid lesion.

(G) RETROPAROTID AND SCALENE NODES – Received are multiple fragments of fibroadipose tissue aggregating to 2.0 x 1.5 x 1.2 cm. The specimen is dissected to reveal six possible lymph nodes ranging from 0.1 up to 0.7 cm in greatest dimension. The specimen is submitted entirely.

SECTION CODE: G1, three possible lymph nodes; G2, three possible lymph nodes.

(H) RIGHT PARATRACHEAL – Received is a 3.0 x 2.0 x 1.0 cm aggregate of fibroadipose tissue. The specimen is dissected to reveal seven possible lymph nodes ranging from 0.3 up to 1.0 cm in greatest dimension. The specimen is submitted entirely.

SECTION CODE: H1, five possible lymph nodes; H2, two possible lymph nodes.

(I) SUPERIOR MEDIASTINAL (PER TERESA) – Received is a 2.0 x 1.0 x 0.8 cm portion of fibroadipose tissue. The specimen is dissected to reveal zero possible lymph nodes. The specimen is submitted entirely in I.

(J) RIGHT ANTERIOR TRACHEAL WALL MEDIAL ASPECT INKED, LATERAL CLIP – A portion of trachea (1.6 x 0.5 x 0.3 cm). The medial aspect is inked blue by the surgeon, and a clip designates lateral. Submitted en toto in J for frozen section.

INK CODE: Blue – medial; Red – lateral.

*FS/DX: PORTION OF TRACHEA, NO TUMOR PRESENT.

(K) LEFT PARATRACHEAL – A 5.0 x 1.0 x 0.2 cm fibrofatty soft tissue fragment with a 1.1 cm x 0.9 cm tan lymph node entirely submitted as follows: K1, one lymph node bisected; K2, remaining adipose tissue, entirely submitted.

(L) LEFT PARATRACHEAL MASS, RULE OUT PARATHYROID – A less than 0.1 cm tan, soft tissue fragment, entirely submitted for frozen section.

*FS/DX: LYMPHOID TISSUE, NO PARATHYROID TISSUE PRESENT.

CLINICAL HISTORY

Papillary thyroid carcinoma.

Page 2 of 4

Surgical Pathology Report

File under: Pathology

[page 3 of 4]
Surgical Pathology Report

Department of Pathology, I

DOB
Physician:

Sex: F

Collected:

Pathologist:

Accession

Received: _

Case type: Surgical Case

cc: _

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by U
These tests have not been specifically cleared or approved by the U.S. Food and Drug Administration."

Entire report and diagnosis completed by: _

Page 3 of 4	
Surgical Pathology Report	
File under: Pathology	

[page 4 of 4]
Surgical Pathology Report

Department of Pathology
Tel

DOE
Physician:

Sex: F

Collected:

Pathologist:

Accession.

Received:

Case type: Surgical Case

cc:

SNOMED CODES

TB600 TC4200 M80503 M80506

Entire report and diagnosis completed by

Page 4 of 4	
Surgical Pathology Report	
File under: Pathology	

Source: NCI Genomic Data Commons file 77a85d3d-f1d4-4581-b268-997bfe0b7334 (TCGA-EL-A3H4.587AB240-F36D-4FE3-B0A5-81C52DD1A6AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).